Somatic mutation profile of tumor specimen 0DLJX4 from CCDI case PBBZKT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.6 years (2,777 days).
Specimen 0DLJX4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9cba2732-e006-48a0-9fc8-5813ad204c91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLJWQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3905403-e5e0-47dc-a12b-65ea7de45f0f

The open-access MAF lists 21 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 3, 3'UTR 2, 5'UTR 2, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 439/1180 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 338/701 reads (48%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 621/873 reads (71%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGAP28 | c.1699C>T p.R567C (on ENST00000383472 / NM_001366230.1; = p.R408C on NM_001010000.3) | Missense Mutation (SNP) | VAF 44/1092 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.479); catalogued as rs751989443, COSV51634353, COSV99151102; called by muse, mutect2
- FLG | c.8372G>A p.G2791E | Missense Mutation (SNP) | VAF 123/1159 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs770743879, COSV64239814; called by muse, mutect2, varscan2
- HHIPL1 | c.2237C>T p.A746V | Missense Mutation (SNP) | VAF 163/403 reads (40%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as rs1024805181; called by muse, mutect2, varscan2
- ITGB2 | c.2218G>A p.G740S (on ENST00000302347; = p.G716S on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 311/717 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1064794297, CM140872; called by muse, mutect2, varscan2
- PCDHGA2 | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 96/823 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.298); catalogued as rs1244580814; called by muse, mutect2, varscan2
- RP1L1 | c.1921C>T p.H641Y | Missense Mutation (SNP) | VAF 120/1176 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs567316993; called by muse, mutect2, varscan2
- C16orf96 | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 242/351 reads (69%) | SIFT tolerated (0.09); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- PLA2G4C | c.503C>A p.P168H | Missense Mutation (SNP) | VAF 108/1504 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RP1L1 | c.5443C>T p.Q1815* | Nonsense Mutation (SNP) | VAF 95/680 reads (14%) | called by muse, mutect2, varscan2
- RP1L1 | c.1741C>G p.L581V | Missense Mutation (SNP) | VAF 123/1260 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.088); called by muse, mutect2
- NCOA7 | c.2340C>T p.S780= | Silent (SNP) | VAF 656/1813 reads (36%) | catalogued as rs138536047; called by muse, mutect2, varscan2
- CACNA2D3 | c.2368+78C>T | Intron (SNP) | VAF 88/207 reads (43%) | called by muse, mutect2, varscan2
- MGAM2 | c.*35C>T | 3'UTR (SNP) | VAF 83/189 reads (44%) | catalogued as rs546455964, COSV72176831; called by muse, mutect2, varscan2
- SKIDA1 | c.-60G>A | 5'UTR (SNP) | VAF 8/281 reads (3%) | called by muse, mutect2
- SKIDA1 | c.-61T>C | 5'UTR (SNP) | VAF 8/279 reads (3%) | catalogued as rs1015442172; called by muse, mutect2
- SRR | c.*986G>C | 3'UTR (SNP) | VAF 80/228 reads (35%) | called by muse, mutect2, varscan2
- TSEN54 | c.1253-10G>T | Intron (SNP) | VAF 214/573 reads (37%) | called by muse, mutect2, varscan2
- ZNF780A | c.-46+859G>A | Intron (SNP) | VAF 102/372 reads (27%) | catalogued as rs1367071304, COSV61814551; called by muse, mutect2, varscan2
